Somatic mutation profile of tumor specimen C3N-04155-01 (aliquot CPT0223790006) from CPTAC case C3N-04155, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 76.8 years (28,060 days).
Specimen C3N-04155-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4df96db7-c928-4f6f-a085-e2530977081b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04155-71 (Blood Derived Normal), aliquot CPT0223910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4746d539-2440-45e3-961b-5a5516b0631f

The open-access MAF lists 401 somatic variants for this specimen: 269 protein-altering or splice-affecting, 86 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 227, Silent 86, Intron 21, Nonsense Mutation 20, RNA 14, 3'UTR 7, Splice Region 6, Splice Site 6, Frame Shift Del 5, 5'UTR 4, Frame Shift Ins 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEAF1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 113/854 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777623, CM145122; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 146/324 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV50260372, COSV50272556, COSV50274400; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 39/324 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 307/406 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ABCC12 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.82); catalogued as COSV100252360; called by muse, mutect2, varscan2
- AIFM3 | c.1779-7C>G | Splice Region (SNP) | VAF 77/428 reads (18%) | catalogued as rs771020603; called by muse, mutect2, varscan2
- AJUBA | c.11T>A p.L4* | Nonsense Mutation (SNP) | VAF 150/282 reads (53%) | catalogued as COSV52986802; called by muse, mutect2, varscan2
- ARVCF | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 190/395 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs560236817, COSV54267213; called by muse, mutect2, varscan2
- ASAP2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 120/354 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1263222293; called by muse, mutect2, varscan2
- ATP9B | c.1223A>G p.N408S | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs374549676; called by muse, mutect2, varscan2
- BBC3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 72/140 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV56262353, COSV56262657; called by muse, mutect2, varscan2
- BNC1 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 33/181 reads (18%) | catalogued as COSV61757124; called by muse, mutect2, varscan2
- CEP78 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs371010271; called by muse, mutect2, varscan2
- CHUK | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100957259; called by muse, mutect2, varscan2
- CLUL1 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs550555452; called by muse, mutect2, varscan2
- CMKLR1 | c.1085G>A p.R362K (on ENST00000312143 / NM_001142344.2; = p.R360K on NM_004072.3) | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56442300; called by muse, mutect2, varscan2
- COL20A1 | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58927962; called by muse, mutect2, varscan2
- CRYBG2 | c.2233G>A p.G745S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.136); catalogued as COSV57485925; called by muse, mutect2, varscan2
- DNMT1 | c.4103G>A p.R1368Q | Missense Mutation (SNP) | VAF 130/597 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs748486662, COSV100531474; called by muse, mutect2, varscan2
- DOCK11 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV52236643; called by muse, mutect2, varscan2
- DOCK11 | c.2341C>G p.L781V | Missense Mutation (SNP) | VAF 93/135 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52246901; called by muse, mutect2, varscan2
- DPPA2 | c.852G>C p.K284N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV72118253; called by muse, mutect2, varscan2
- DPPA4 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV59512767; called by muse, mutect2, varscan2
- DSCAML1 | c.2107G>T p.V703L (on ENST00000321322; = p.V643L on NM_020693.4) | Missense Mutation (SNP) | VAF 182/607 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as rs1261190835; called by muse, mutect2, varscan2
- FAM135B | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52733210, COSV52757897; called by muse, mutect2, varscan2
- FLT3 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54061277; called by muse, mutect2, varscan2
- FRG1BP | n.306-1G>A | Splice Site (SNP) | VAF 18/152 reads (12%) | catalogued as rs1261342283; called by muse, varscan2
- FRY | c.7063G>T p.G2355W | Missense Mutation (SNP) | VAF 101/674 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV66573062; called by muse, mutect2, varscan2
- GPC5 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 114/197 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs1182250552; called by muse, mutect2, varscan2
- GPRASP1 | c.2460G>T p.E820D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.412); catalogued as COSV64355979; called by muse, mutect2, varscan2
- GRIK3 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277838021, COSV66135068; called by muse, mutect2, varscan2
- HIPK4 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 830/996 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764129980, COSV52520798; called by muse, mutect2, varscan2
- HSPG2 | c.12442C>T p.Q4148* | Nonsense Mutation (SNP) | VAF 62/273 reads (23%) | catalogued as COSV60829761; called by muse, mutect2, varscan2
- IL31 | c.389C>G p.T130S | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV65476220; called by muse, mutect2, varscan2
- IRF2BPL | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 151/384 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV53148825; called by muse, mutect2, varscan2
- ISLR2 | c.1278C>A p.S426R | Missense Mutation (SNP) | VAF 197/661 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs752419127; called by muse, mutect2, varscan2
- ITPKC | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 114/2552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54574303, COSV99648935; called by muse, mutect2
- KAT6B | c.3404G>A p.R1135H | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138617006, COSV54741411; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIAA1109 | c.2242A>G p.I748V | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs772520081; called by muse, mutect2, varscan2
- KIAA1522 | c.2682C>A p.N894K (on ENST00000373480 / NM_001198972.2; = p.N953K on NM_020888.3) | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.066); catalogued as rs370887196; called by muse, mutect2, varscan2
- KIF5C | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV101276122; called by muse, mutect2, varscan2
- KRTAP19-8 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.801); catalogued as COSV101239215; called by muse, mutect2, varscan2
- LIMCH1 | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 37/170 reads (22%) | catalogued as COSV58297593; called by muse, mutect2, varscan2
- LINGO3 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1206241337, COSV68261321; called by muse, mutect2, varscan2
- LMOD2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1438528282, COSV71755637; called by muse, mutect2, varscan2
- LRRTM1 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 89/278 reads (32%) | catalogued as COSV99701753; called by muse, mutect2, varscan2
- MFSD9 | c.497C>G p.P166R | Missense Mutation (SNP) | VAF 204/582 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753732232, COSV99302185; called by muse, mutect2, varscan2
- MMEL1 | c.2306C>A p.P769H | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as rs780473644; called by muse, mutect2, varscan2
- MOCOS | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 100/422 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54342745; called by muse, mutect2, varscan2
- MYH6 | c.736G>T p.G246W | Missense Mutation (SNP) | VAF 181/334 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62447609; called by muse, mutect2, varscan2
- MYOM1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs780023288, COSV99865541; called by muse, mutect2, varscan2
- NQO2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 144/307 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.112); catalogued as rs144400431; called by muse, mutect2, varscan2
- NTRK3 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 204/657 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs761690006, COSV58124028; called by muse, mutect2, varscan2
- NXNL1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV57324783; called by muse, varscan2
- OARD1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.214); catalogued as rs770268622, COSV55107310; called by muse, mutect2
- OGFOD2 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.706); catalogued as rs759379455; called by muse, mutect2, varscan2
- OR14C36 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1434603157; called by muse, mutect2, varscan2
- OR2A5 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1214801513, COSV101278772; called by muse, mutect2, varscan2
- OR2L3 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV63455769; called by muse, varscan2
- OR2M5 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV63546077; called by muse, mutect2, varscan2
- OR56B1 | c.555C>A p.H185Q | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs1418184190; called by muse, mutect2, varscan2
- PLEKHG3 | c.2593C>T p.R865C (on ENST00000394691; = p.R921C on NM_001308147.2) | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs372514153; called by muse, mutect2, varscan2
- PROX2 | c.1076G>A p.W359* | Nonsense Mutation (SNP) | VAF 150/386 reads (39%) | catalogued as rs751309959; called by muse, mutect2, varscan2
- PTPRN2 | c.1705G>C p.D569H | Missense Mutation (SNP) | VAF 167/486 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV67034029; called by muse, mutect2, varscan2
- PXDNL | c.2293C>G p.R765G | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62477231, COSV62488190; called by muse, mutect2, varscan2
- RIN3 | c.2402C>T p.T801M | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs369913502; called by muse, mutect2, varscan2
- RYR2 | c.12292G>T p.V4098F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV63661279, COSV63692480; called by muse, mutect2, varscan2
- SAMD3 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100148140, COSV60775512; called by muse, mutect2, varscan2
- SGF29 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 105/176 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1408456821; called by muse, mutect2, varscan2
- SH3PXD2A | c.1778C>T p.S593L (on ENST00000369774 / NM_001365079.1; = p.S565L on NM_014631.2) | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.782); catalogued as rs776936856; called by muse, mutect2, varscan2
- SLC38A7 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV54703019, COSV99543686; called by muse, mutect2
- SLC5A2 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 92/428 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as rs1250100950; called by muse, mutect2, varscan2
- STYXL2 | c.3399C>A p.D1133E | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as COSV54803612; called by muse, mutect2, varscan2
- SVEP1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV57045783; called by muse, mutect2, varscan2
- SVEP1 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 56/442 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100238483; called by muse, varscan2
- TBC1D9B | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 176/908 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs188882073; called by muse, varscan2
- THSD7A | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs776111424, COSV70263836; called by muse, mutect2, varscan2
- TLN2 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV60884920; called by muse, mutect2, varscan2
- TMEM132C | c.2960C>A p.A987E | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as rs1181592725, COSV59430870; called by muse, mutect2, varscan2
- TMLHE | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 57/90 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145371120, COSV57686266; called by muse, mutect2, varscan2
- TMX3 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs532843708; called by muse, mutect2, varscan2
- TRANK1 | c.7946A>T p.E2649V | Missense Mutation (SNP) | VAF 170/304 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV100084403; called by muse, mutect2, varscan2
- TRIM51 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV55267086; called by muse, mutect2, varscan2
- TRIOBP | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 146/1153 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1278990406, COSV100730751; called by muse, mutect2, varscan2
- TRPM6 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 220/348 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs368805281; called by muse, mutect2, varscan2
- TTC13 | c.1622C>G p.A541G | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.763); catalogued as rs1055332227; called by muse, mutect2, varscan2
- TTN | c.61641C>G p.I20547M (on ENST00000591111; = p.I13123M on NM_003319.4) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | PolyPhen probably damaging (0.997); catalogued as COSV100624784; called by muse, mutect2, varscan2
- USH2A | c.9705G>T p.Q3235H | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1423116732; called by muse, mutect2, varscan2
- VPS29 | c.3+7G>A | Splice Region (SNP) | VAF 89/464 reads (19%) | catalogued as rs1032838017; called by muse, mutect2, varscan2
- XKR4 | c.822A>G p.I274M | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.153); catalogued as COSV59319271; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1065G>C p.K355N | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1443743449; called by muse, mutect2, varscan2
- ZNF365 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV101237946; called by muse, mutect2, varscan2
- ZNF525 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 69/157 reads (44%) | catalogued as rs267605655, COSV62491965; called by muse, mutect2, varscan2
- ZNF528 | c.1539A>T p.K513N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as COSV64619572; called by muse, mutect2, varscan2
- ZNF571 | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV60732690; called by muse, mutect2
- ZNF598 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs371463041; called by muse, mutect2, varscan2
- ZNF679 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55382373, COSV99739045; called by muse, mutect2, varscan2
- ZNF99 | c.1643A>G p.N548S | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as rs764884829, COSV101233872; called by muse, mutect2, varscan2
- ABCA5 | c.2064A>T p.Q688H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACP3 | c.590T>A p.L197* | Nonsense Mutation (SNP) | VAF 89/249 reads (36%) | called by muse, mutect2, varscan2
- ADA2 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAMTS15 | c.2834G>T p.C945F | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRV1 | c.10666G>C p.V3556L | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADH6 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AF196969.1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 137/206 reads (67%) | SIFT tolerated (0.71); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AMBN | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AMY2A | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPT2 | c.1368C>A p.N456K | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKFN1 | c.853A>T p.T285S | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ANKH | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 992/1434 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD30B | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARID1A | c.4619A>T p.N1540I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ATP7B | c.2319C>A p.F773L | Missense Mutation (SNP) | VAF 295/464 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8A1 | c.3213-1G>C p.X1071_splice | Splice Site (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- AUNIP | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AUP1 | c.354T>G p.S118R | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- BPNT2 | c.647-2A>T p.X216_splice | Splice Site (SNP) | VAF 117/309 reads (38%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.3090C>A p.N1030K (on ENST00000479441 / NM_001174051.3; = p.N1023K on NM_006030.4) | Missense Mutation (SNP) | VAF 116/218 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CACNA2D4 | c.452_453insGGG p.A151_D152insG | In Frame Ins (INS) | VAF 68/237 reads (29%) | called by mutect2, varscan2
- CACTIN | c.1370A>T p.H457L | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CCDC65 | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 104/548 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- CD1B | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CD82 | c.643-1G>T p.X215_splice | Splice Site (SNP) | VAF 98/272 reads (36%) | called by muse, mutect2, varscan2
- CEP350 | c.872_882del p.K291Tfs*16 | Frame Shift Del (DEL) | VAF 66/253 reads (26%) | called by pindel, varscan2*
- CEP83 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CFAP91 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 152/621 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHAF1B | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLPTM1L | c.1146+8T>G | Splice Region (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- CLTC | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CR1 | c.4625C>A p.T1542K | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- CSMD3 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CTC1 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTTNBP2 | c.1680C>G p.H560Q | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DAW1 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DCC | c.521A>T p.Q174L | Missense Mutation (SNP) | VAF 191/562 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DCHS1 | c.9514C>T p.Q3172* | Nonsense Mutation (SNP) | VAF 92/282 reads (33%) | called by muse, mutect2, varscan2
- DDAH1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DDN | c.1895A>T p.E632V | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.118); called by muse, varscan2
- DOCK4 | c.1630A>G p.K544E | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DYNC2I1 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- DYNLL1 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- E2F4 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EHBP1L1 | c.2582C>G p.A861G | Missense Mutation (SNP) | VAF 104/191 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EOGT | c.1026C>G p.F342L | Missense Mutation (SNP) | VAF 86/175 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ESRRB | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 220/516 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F5 | c.3103G>T p.E1035* | Nonsense Mutation (SNP) | VAF 124/350 reads (35%) | called by muse, mutect2, varscan2
- FAM162A | c.4_8dup p.S3? | Frame Shift Ins (INS) | VAF 134/663 reads (20%) | called by mutect2, pindel, varscan2
- FAM181B | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- FAP | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.6643T>G p.S2215A | Missense Mutation (SNP) | VAF 58/676 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- FLT1 | c.3854C>T p.S1285F | Missense Mutation (SNP) | VAF 372/690 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- FOCAD | c.800A>G p.Q267R | Missense Mutation (SNP) | VAF 130/233 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FREM3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FRRS1 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2
- FZD3 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GAN | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCA | c.193-1G>T p.X65_splice | Splice Site (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- GFPT2 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GK3P | c.470T>A p.L157H | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GLI2 | c.2639C>T p.T880I (on ENST00000361492 / NM_001374353.1; = p.T897I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/507 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- GMDS | c.783G>C p.L261F | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- GORASP2 | c.63G>C p.R21= | Splice Region (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- H2AW | c.330del p.N111Tfs*60 | Frame Shift Del (DEL) | VAF 235/739 reads (32%) | called by mutect2, pindel, varscan2
- HMCN2 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 200/368 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HMGXB4 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- HOXD10 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IGKV2D-28 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by mutect2, varscan2
- IGLV7-46 | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 89/673 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- IQCD | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRGC | c.410_421del p.F137_V140del | In Frame Del (DEL) | VAF 40/220 reads (18%) | called by pindel, varscan2
- IRGC | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, varscan2
- KBTBD11 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH7 | c.3466C>G p.L1156V | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNN2 | c.1446G>T p.L482F (on ENST00000264773; = p.L694F on NM_021614.4) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- KDM3B | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 210/389 reads (54%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF6 | c.2386A>T p.I796F | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF6 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KPNA2 | c.300C>T p.A100= | Splice Region (SNP) | VAF 61/264 reads (23%) | called by muse, mutect2, varscan2
- KRT85 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 312/751 reads (42%) | called by muse, mutect2, varscan2
- LILRB5 | c.482A>T p.K161M | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- LMTK3 | c.766C>A p.H256N | Missense Mutation (SNP) | VAF 137/269 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LMX1A | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 105/467 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MACF1 | c.14557G>C p.G4853R (on ENST00000372915; = p.G2786R on NM_012090.5) | Missense Mutation (SNP) | VAF 118/331 reads (36%) | called by muse, mutect2, varscan2
- MAGEA3 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 173/535 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MB21D2 | c.676G>C p.V226L | Missense Mutation (SNP) | VAF 154/740 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MED13L | c.2117G>T p.G706V | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MROH2B | c.1541T>G p.L514R | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL38 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 168/700 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MS4A2 | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 77/518 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- MSANTD3 | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 204/397 reads (51%) | called by muse, mutect2, varscan2
- MTMR4 | c.2375A>T p.Q792L | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH1 | c.2805G>T p.E935D | Missense Mutation (SNP) | VAF 458/820 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, varscan2
- MYOM1 | c.2422A>G p.I808V | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NAALAD2 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- NAB1 | c.1038_1041del p.Q346Hfs*24 | Frame Shift Del (DEL) | VAF 30/168 reads (18%) | called by mutect2, pindel, varscan2
- NFKB1 | c.875G>C p.G292A (on ENST00000394820 / NM_001382627.1; = p.G293A on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- NPTX2 | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 72/401 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- NUDT6 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUMA1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NXF3 | c.13T>A p.S5T | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXNL1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.5); called by muse, varscan2
- OR12D2 | c.418A>T p.T140S | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR2AJ1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR2T12 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 95/484 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR51T1 | c.563A>T p.K188I | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- OR5B3 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- OR5L2 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OSBP2 | c.2646G>C p.E882D | Missense Mutation (SNP) | VAF 206/400 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.22); called by muse, mutect2
- PAFAH2 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PALM3 | c.1499C>A p.T500N (on ENST00000340790; = p.T515N on NM_001145028.2) | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PCDH7 | c.2587C>T p.Q863* | Nonsense Mutation (SNP) | VAF 60/228 reads (26%) | called by muse, mutect2, varscan2
- PDLIM5 | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, varscan2
- PKDREJ | c.5092A>G p.K1698E | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- POM121C | c.3467G>A p.G1156E (on ENST00000607367; = p.G914E on NM_001099415.3) | Missense Mutation (SNP) | VAF 95/401 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- POMK | c.824C>G p.S275* | Nonsense Mutation (SNP) | VAF 88/194 reads (45%) | called by muse, mutect2, varscan2
- PRKAG3 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PROS1 | c.965G>T p.R322I | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRTG | c.3238C>G p.P1080A | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PTBP2 | c.1516C>T p.Q506* (on ENST00000426398 / NM_001300986.2; = p.Q497* on NM_021190.4) | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- PWWP2A | c.1225A>G p.K409E | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- RABGGTB | c.344A>G p.D115G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RASSF4 | c.625A>G p.K209E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM46 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RCSD1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 78/385 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- RERE | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 99/427 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RIMS1 | c.840G>C p.Q280H | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RNF10 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RUSC1 | c.1533+6G>A | Splice Region (SNP) | VAF 101/410 reads (25%) | called by muse, mutect2, varscan2
- RXFP3 | c.1044G>A p.W348* | Nonsense Mutation (SNP) | VAF 285/809 reads (35%) | called by muse, mutect2, varscan2
- SCRIB | c.3568G>C p.D1190H | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SEC16B | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SERPINA12 | c.228del p.L77* | Frame Shift Del (DEL) | VAF 169/469 reads (36%) | called by mutect2, pindel, varscan2
- SGCD | c.611del p.P204Qfs*21 (on ENST00000435422 / NM_001128209.2; = p.P205Qfs*21 on NM_000337.5) | Frame Shift Del (DEL) | VAF 55/178 reads (31%) | called by mutect2, pindel, varscan2
- SHOC1 | c.3973C>G p.Q1325E | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SLC13A1 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A6 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC26A3 | c.2059G>C p.D687H | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SLC29A3 | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 216/366 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SMCHD1 | c.4846G>T p.D1616Y | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SNORC | c.319G>C p.V107L | Missense Mutation (SNP) | VAF 132/307 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SSU72P8 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- STON1 | c.2150_2151insT p.K717Nfs*4 | Frame Shift Ins (INS) | VAF 80/236 reads (34%) | called by mutect2, varscan2
- SUN5 | c.366A>T p.L122F | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- TAAR1 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TANC1 | c.2636C>A p.T879K | Missense Mutation (SNP) | VAF 113/293 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- TANC2 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 89/603 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TENT4B | c.565C>G p.R189G (on ENST00000561678 / NM_001365323.2; = p.R174G on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMCC1 | c.1512-1G>T p.X504_splice (on ENST00000393238 / NM_001349268.2; = p.X180_splice on NM_015008.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 30/178 reads (17%) | called by muse, mutect2
- TMEM39A | c.503G>A p.W168* | Nonsense Mutation (SNP) | VAF 40/307 reads (13%) | called by muse, mutect2, varscan2
- TMX2 | c.156A>T p.Q52H | Missense Mutation (SNP) | VAF 176/403 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- TONSL | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 124/688 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV26-1 | c.264C>A p.S88R | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TRIM36 | c.1469C>A p.A490D | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TRIM55 | c.1490G>C p.G497A | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.866); called by muse, varscan2
- TRPM3 | c.3474G>T p.M1158I (on ENST00000357533 / NM_001366142.2; = p.M1013I on NM_020952.6) | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSBP1 | c.134G>C p.S45T | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TSEN34 | c.686A>G p.E229G | Missense Mutation (SNP) | VAF 280/508 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TTC22 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 195/737 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TUBB8B | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 160/550 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.772); called by muse, varscan2
- URI1 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 358/449 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VARS2 | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 160/371 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- VPS13B | c.1490C>G p.S497* | Nonsense Mutation (SNP) | VAF 27/181 reads (15%) | called by muse, mutect2, varscan2
- VRTN | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR64 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- YIPF3 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZBTB26 | c.1053T>A p.D351E | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.349); called by muse, mutect2
- ZNF408 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ABCA10 | c.2076A>C p.T692= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as COSV52228760; called by muse, mutect2, varscan2
- ADRM1 | c.1062C>A p.P354= | Silent (SNP) | VAF 64/403 reads (16%) | called by muse, mutect2, varscan2
- ADSS2 | c.1218A>G p.P406= | Silent (SNP) | VAF 83/210 reads (40%) | catalogued as rs373775554; called by muse, mutect2, varscan2
- AMBN | c.288T>G p.T96= | Silent (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- ANKRD12 | c.2148A>G p.E716= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- ANKRD30B | c.2211C>G p.L737= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs780434761; called by muse, varscan2
- ARHGEF10L | c.1797G>A p.V599= | Silent (SNP) | VAF 59/239 reads (25%) | catalogued as rs778897933; called by muse, mutect2, varscan2
- ARMC9 | c.1311G>T p.G437= | Silent (SNP) | VAF 73/156 reads (47%) | catalogued as rs754737763; called by muse, mutect2, varscan2
- ART4 | c.117C>A p.G39= | Silent (SNP) | VAF 46/248 reads (19%) | catalogued as rs1478713265; called by muse, mutect2, varscan2
- ASPM | c.7989A>T p.A2663= | Silent (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- ATP10D | c.1728T>C p.N576= | Silent (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- ATP2B2 | c.3453G>T p.S1151= (on ENST00000352432; = p.S1117= on NM_001330611.3) | Silent (SNP) | VAF 104/251 reads (41%) | called by muse, mutect2, varscan2
- ATP8B2 | c.12G>A p.L4= | Silent (SNP) | VAF 39/295 reads (13%) | catalogued as COSV100270447; called by muse, mutect2, varscan2
- ATRN | c.2811A>G p.T937= | Silent (SNP) | VAF 109/282 reads (39%) | catalogued as COSV53525665; called by muse, mutect2, varscan2
- C9 | c.438G>T p.V146= | Silent (SNP) | VAF 76/494 reads (15%) | called by mutect2, varscan2
- CACNA1G | c.3681G>A p.E1227= | Silent (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2, varscan2
- CAMKK2 | c.1257G>A p.L419= | Silent (SNP) | VAF 49/476 reads (10%) | catalogued as rs771727169; called by muse, mutect2, varscan2
- CCDC191 | c.2004A>G p.R668= | Silent (SNP) | VAF 19/219 reads (9%) | called by muse, mutect2
- CCDC59 | c.240A>C p.S80= | Silent (SNP) | VAF 51/138 reads (37%) | called by muse, mutect2, varscan2
- CDC20B | c.84C>T p.L28= | Silent (SNP) | VAF 99/331 reads (30%) | catalogued as rs912664435; called by muse, mutect2, varscan2
- CHAMP1 | c.465G>A p.E155= | Silent (SNP) | VAF 126/205 reads (61%) | called by muse, mutect2, varscan2
- CLDN11 | c.147C>A p.S49= | Silent (SNP) | VAF 217/2169 reads (10%) | called by muse, mutect2, varscan2
- COG8 | c.1656C>A p.L552= | Silent (SNP) | VAF 297/541 reads (55%) | called by muse, mutect2, varscan2
- CSMD3 | c.2010C>T p.P670= (on ENST00000297405 / NM_001363185.1; = p.P566= on NM_052900.3) | Silent (SNP) | VAF 52/166 reads (31%) | catalogued as COSV52120981; called by muse, mutect2, varscan2
- DMBT1 | c.4959C>G p.V1653= (on ENST00000338354 / NM_001377530.1; = p.V896= on NM_004406.3) | Silent (SNP) | VAF 259/456 reads (57%) | catalogued as COSV100352708; called by muse, mutect2, varscan2
- EPG5 | c.6519G>A p.P2173= | Silent (SNP) | VAF 57/378 reads (15%) | catalogued as rs762400421; called by muse, mutect2, varscan2
- FBXO7 | c.1056C>G p.V352= | Silent (SNP) | VAF 176/373 reads (47%) | catalogued as rs1226445050; called by muse, mutect2, varscan2
- FPR1 | c.93G>T p.L31= | Silent (SNP) | VAF 113/219 reads (52%) | catalogued as rs1044585176; called by muse, mutect2, varscan2
- GK3P | c.471C>A p.L157= | Silent (SNP) | VAF 39/384 reads (10%) | catalogued as rs370239408; called by muse, mutect2
- GPR171 | c.246G>T p.L82= | Silent (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2
- H2BC14 | c.201C>T p.V67= | Silent (SNP) | VAF 157/517 reads (30%) | catalogued as rs374316577; called by muse, mutect2, varscan2
- IGKV2D-29 | c.261C>T p.F87= | Silent (SNP) | VAF 113/494 reads (23%) | called by muse, mutect2, varscan2
- INPP4B | c.129C>T p.F43= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1312212472; called by muse, mutect2, varscan2
- INPP5D | c.318G>A p.E106= | Silent (SNP) | VAF 57/253 reads (23%) | catalogued as COSV64037096; called by muse, mutect2, varscan2
- ITGAV | c.153C>T p.F51= | Silent (SNP) | VAF 43/257 reads (17%) | catalogued as rs1157905919, COSV53710618; called by muse, mutect2
- LAMA2 | c.1230A>C p.P410= | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, varscan2
- MADD | c.2394A>G p.Q798= | Silent (SNP) | VAF 74/198 reads (37%) | called by muse, mutect2, varscan2
- MAN2A1 | c.1938G>A p.E646= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- MCF2L2 | c.2958T>C p.N986= | Silent (SNP) | VAF 88/504 reads (17%) | catalogued as COSV100193562; called by muse, mutect2, varscan2
- MFSD9 | c.498G>T p.P166= | Silent (SNP) | VAF 206/593 reads (35%) | catalogued as COSV51493515; called by muse, mutect2, varscan2
- MYO16 | c.4899C>G p.P1633= | Silent (SNP) | VAF 149/291 reads (51%) | catalogued as COSV100696729; called by muse, mutect2, varscan2
- MYO3B | c.2337G>A p.P779= | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as rs201316029, COSV58711422, COSV58714238; called by muse, mutect2
- N6AMT1 | c.123C>G p.A41= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as COSV58134860; called by muse, mutect2, varscan2
- NOS2 | c.765C>T p.H255= | Silent (SNP) | VAF 64/211 reads (30%) | catalogued as rs201952222; called by muse, mutect2, varscan2
- NUP98 | c.1725C>G p.L575= | Silent (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- OBSCN | c.17838G>C p.V5946= | Silent (SNP) | VAF 81/317 reads (26%) | called by muse, mutect2, varscan2
- OLFM1 | c.261G>T p.R87= (on ENST00000371793 / NM_001282611.2; = p.R69= on NM_006334.4) | Silent (SNP) | VAF 48/343 reads (14%) | called by muse, mutect2, varscan2
- OR2A5 | c.198C>T p.A66= | Silent (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- OR2M2 | c.843C>T p.L281= | Silent (SNP) | VAF 112/318 reads (35%) | called by muse, mutect2, varscan2
- OR9A4 | c.456G>T p.G152= | Silent (SNP) | VAF 38/225 reads (17%) | called by muse, mutect2, varscan2
- PAQR9 | c.861C>A p.A287= | Silent (SNP) | VAF 110/404 reads (27%) | catalogued as COSV61418962; called by muse, mutect2, varscan2
- PCDHGA11 | c.408G>A p.E136= | Silent (SNP) | VAF 44/178 reads (25%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.234C>T p.S78= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- PDE4B | c.2046G>T p.L682= | Silent (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
- PDGFRB | c.816C>T p.I272= | Silent (SNP) | VAF 67/241 reads (28%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.1227G>C p.L409= | Silent (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- PIK3C2A | c.4494T>C p.D1498= | Silent (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- PLCH2 | c.1386C>G p.L462= | Silent (SNP) | VAF 58/192 reads (30%) | called by muse, mutect2, varscan2
- POFUT1 | c.672C>T p.A224= | Silent (SNP) | VAF 41/307 reads (13%) | called by muse, mutect2, varscan2
- RBM12B | c.24G>A p.L8= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1265752115; called by muse, mutect2, varscan2
- RNGTT | c.483A>T p.P161= | Silent (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
- SASH1 | c.2805G>A p.Q935= | Silent (SNP) | VAF 200/343 reads (58%) | called by muse, mutect2, varscan2
- SEMA5A | c.1854G>A p.R618= | Silent (SNP) | VAF 92/454 reads (20%) | called by muse, mutect2, varscan2
- SLC25A37 | c.702G>T p.P234= | Silent (SNP) | VAF 57/146 reads (39%) | catalogued as rs368174643; called by muse, mutect2, varscan2
- SLC38A7 | c.1263G>A p.E421= | Silent (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2
- SLC45A2 | c.555C>T p.L185= | Silent (SNP) | VAF 123/443 reads (28%) | called by muse, mutect2, varscan2
- SORCS1 | c.2046G>A p.Q682= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- SPATA6 | c.12G>A p.V4= | Silent (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- SPHKAP | c.1770G>T p.P590= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as rs141688278; called by muse, mutect2, varscan2
- SV2C | c.126C>A p.T42= | Silent (SNP) | VAF 66/215 reads (31%) | called by muse, mutect2, varscan2
- TBC1D15 | c.81C>T p.T27= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- TP53RK | c.132G>A p.E44= | Silent (SNP) | VAF 119/696 reads (17%) | called by muse, mutect2, varscan2
- TRIM49D1 | c.1092G>C p.G364= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- TRIM51GP | c.1296C>T p.Y432= | Silent (SNP) | VAF 61/206 reads (30%) | called by muse, mutect2, varscan2
- TRIOBP | c.5415G>A p.S1805= (on ENST00000644935 / NM_001039141.3; = p.S92= on NM_007032.5) | Silent (SNP) | VAF 384/709 reads (54%) | catalogued as rs751311447; called by muse, mutect2, varscan2
- TTN | c.73338T>C p.D24446= (on ENST00000591111; = p.D17022= on NM_003319.4) | Silent (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.56184C>T p.I18728= (on ENST00000591111; = p.I11304= on NM_003319.4) | Silent (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- XIRP1 | c.2322C>T p.T774= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as rs914153141; called by muse, mutect2, varscan2
- XXYLT1 | c.738G>A p.L246= | Silent (SNP) | VAF 62/503 reads (12%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.474C>T p.I158= | Silent (SNP) | VAF 45/408 reads (11%) | called by muse, mutect2, varscan2
- ZFAND2B | c.546G>A p.P182= | Silent (SNP) | VAF 50/337 reads (15%) | catalogued as rs372552283; called by muse, mutect2, varscan2
- ZFPM2 | c.261G>A p.P87= | Silent (SNP) | VAF 42/269 reads (16%) | catalogued as rs755810063, COSV68274575, COSV68280427; called by muse, mutect2, varscan2
- ZGRF1 | c.1392A>G p.T464= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs764959242; called by muse, mutect2, varscan2
- ZMYND19 | c.246G>T p.P82= | Silent (SNP) | VAF 285/546 reads (52%) | called by muse, mutect2, varscan2
- ZNF100 | c.252G>C p.L84= | Silent (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- ZNF285 | c.1593C>T p.L531= | Silent (SNP) | VAF 90/178 reads (51%) | called by muse, mutect2, varscan2
- AC138749.1 | n.561C>T | RNA (SNP) | VAF 30/282 reads (11%) | called by muse, mutect2, varscan2
- ACAD10 | c.*490G>T | 3'UTR (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- ADCY5 | c.2930+319G>T | Intron (SNP) | VAF 18/224 reads (8%) | catalogued as COSV100567853; called by muse, mutect2
- ADGB | c.4818+5395C>A | Intron (SNP) | VAF 136/257 reads (53%) | called by muse, mutect2, varscan2
- AL359195.2 | n.3437C>T | RNA (SNP) | VAF 104/194 reads (54%) | catalogued as rs756258665; called by muse, mutect2, varscan2
- AL772337.1 | n.476G>T | RNA (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2
- APBA2 | c.952-3823G>T | Intron (SNP) | VAF 93/148 reads (63%) | called by muse, mutect2, varscan2
- CCDC74B | c.1007+12A>T | Intron (SNP) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- CD1D | c.*13C>T | 3'UTR (SNP) | VAF 73/220 reads (33%) | catalogued as rs372611201; called by muse, mutect2, varscan2
- CGREF1 | c.718+13G>C | Intron (SNP) | VAF 112/272 reads (41%) | called by muse, varscan2
- CRB1 | c.2677-449C>G | Intron (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- CYP2A7P2 | n.248T>C | RNA (SNP) | VAF 58/1497 reads (4%) | catalogued as rs1344496440; called by muse, mutect2
- DBNL | c.-19G>T | 5'UTR (SNP) | VAF 41/251 reads (16%) | called by muse, mutect2, varscan2
- DCHS2 | n.3296C>T | RNA (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2, varscan2
- DDX46 | c.1544-318G>A | Intron (SNP) | VAF 51/167 reads (31%) | called by muse, mutect2, varscan2
- DENND5B | c.128-4573G>C | Intron (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- DNM1L | c.*1505C>G | 3'UTR (SNP) | VAF 20/47 reads (43%) | catalogued as rs950395617; called by muse, mutect2, varscan2
- DOCK2 | c.3072+1810G>A | Intron (SNP) | VAF 61/357 reads (17%) | called by muse, mutect2, varscan2
- EFCAB3 | c.-17A>T | 5'UTR (SNP) | VAF 76/207 reads (37%) | called by muse, mutect2, varscan2
- GALK1 | c.-47C>G | 5'UTR (SNP) | VAF 89/422 reads (21%) | called by muse, mutect2, varscan2
- GATA6 | c.*10G>A | 3'UTR (SNP) | VAF 44/204 reads (22%) | catalogued as rs1459688319, COSV52526846, COSV99333538; called by muse, mutect2, varscan2
- GSDMD | c.411-114A>C | Intron (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- GSN | c.1740+25G>A | Intron (SNP) | VAF 307/556 reads (55%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2767G>A | Intron (SNP) | VAF 90/304 reads (30%) | called by muse, mutect2, varscan2
- KIAA1958 | c.-25+18C>A | Intron (SNP) | VAF 42/87 reads (48%) | catalogued as rs1487802304; called by muse, mutect2, varscan2
- KIAA2012 | c.369+1895C>T | Intron (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- KRT8P11 | n.1104T>C | RNA (SNP) | VAF 365/780 reads (47%) | called by muse, mutect2, varscan2
- LINC01583 | n.249G>T | RNA (SNP) | VAF 197/585 reads (34%) | called by muse, mutect2, varscan2
- LINC02817 | n.471G>T | RNA (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- LINC02876 | n.434C>A | RNA (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- MGAM | c.4618+1216A>G | Intron (SNP) | VAF 87/233 reads (37%) | called by muse, mutect2, varscan2
- MIR1827 | n.50G>T | RNA (SNP) | VAF 75/206 reads (36%) | called by muse, mutect2, varscan2
- MIR572 | n.9C>T | RNA (SNP) | VAF 51/149 reads (34%) | called by muse, mutect2, varscan2
- MPI | c.1053+29T>C | Intron (SNP) | VAF 176/492 reads (36%) | called by muse, mutect2, varscan2
- NCAM1 | c.2456+1082G>C | Intron (SNP) | VAF 51/225 reads (23%) | called by muse, mutect2, varscan2
- NDUFS8 | c.110-40G>A | Intron (SNP) | VAF 88/355 reads (25%) | called by muse, mutect2, varscan2
- PKM | c.*139G>T | 3'UTR (SNP) | VAF 135/515 reads (26%) | called by muse, mutect2, varscan2
- REEP6 | c.*161G>T | 3'UTR (SNP) | VAF 93/334 reads (28%) | called by muse, mutect2, varscan2
- RNASEH2A | c.*19C>G | 3'UTR (SNP) | VAF 122/631 reads (19%) | called by muse, mutect2, varscan2
- RPL36A | c.-19C>G | 5'UTR (SNP) | VAF 43/176 reads (24%) | catalogued as COSV100437951; called by muse, mutect2, varscan2
- SSPOP | n.4654C>T | RNA (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- STEAP3 | c.-77+7097G>A | Intron (SNP) | VAF 75/381 reads (20%) | called by muse, mutect2, varscan2
- TRIM51BP | n.1117G>T | RNA (SNP) | VAF 28/188 reads (15%) | called by mutect2, varscan2
- TTN | c.10361-3691G>C | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- TYROBP | c.229+51G>T | Intron (SNP) | VAF 44/357 reads (12%) | called by muse, mutect2, varscan2
- ZNF812P | n.914C>G | RNA (SNP) | VAF 58/137 reads (42%) | called by muse, mutect2, varscan2
